Surgical pathology report (de-identified scan), TCGA case TCGA-22-5477, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5477-01A (Primary Tumor).

TCGA-22-5477

DIAGNOSIS:

Lung, right inferior segment lower lobe, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma forming a 3.5 x 3.2 x 2.8 cm nodule. The tumor puckers but does not involve the pleural surface. The resection margins are negative for tumor. A single intrapulmonary lymph node is negative for tumor. The adjacent lung parenchyma shows emphysematous changes.

Lymph nodes, bronchus intermedius, superior and inferior mediastinal, excision: Multiple bronchus intermedius (1), superior mediastinal (7 right lower paratracheal), inferior mediastinal (2 subcarinal, 1 pulmonary ligament) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 5253bc7c-edaa-4668-88f9-840ae6258232 (TCGA-22-5477.9DCDC788-4EBD-4376-AB97-B0602A684B90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).